Somatic mutation profile of tumor specimen 77c493b1-34ba-4efc-8def-987116 (aliquot 77c493b1-34ba-4efc-8def-987116_D6) from CPTAC case 11CO079, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 77c493b1-34ba-4efc-8def-987116: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dadc6618-f337-4f32-aa64-f9dfa872ca5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a266a66e-f9fb-4056-96a5-0f6c55 (Blood Derived Normal), aliquot a266a66e-f9fb-4056-96a5-0f6c55_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48f60a7d-72a0-4144-8e8b-2b748d9a3453

The open-access MAF lists 118 somatic variants for this specimen: 74 protein-altering or splice-affecting, 29 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 29, Nonsense Mutation 6, Intron 6, Frame Shift Del 5, 3'UTR 3, RNA 3, Splice Site 2, Splice Region 2, 5'UTR 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 125/374 reads (33%) | catalogued as rs121913462, CM077502, COSV57322511, COSV57366061, COSV57375983; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 178/280 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD60 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 124/256 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.383); catalogued as rs760851192, COSV100959266; called by muse, varscan2
- ASH1L | c.5644G>A p.E1882K | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as rs1447857931; called by muse, mutect2, varscan2
- ASIC3 | c.535-7G>A | Splice Region (SNP) | VAF 153/280 reads (55%) | catalogued as rs752414495; called by muse, mutect2, varscan2
- CD53 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs369006161, COSV54760274; called by muse, mutect2, varscan2
- DEPP1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as rs757249362; called by muse, mutect2, varscan2
- DSG1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 105/157 reads (67%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs770916767, COSV57134860; called by muse, mutect2, varscan2
- EFS | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs780224177; called by muse, mutect2
- FAM135B | c.2696C>A p.A899E | Missense Mutation (SNP) | VAF 132/311 reads (42%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV52711475; called by muse, mutect2, varscan2
- GCN1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 102/219 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100324738; called by muse, mutect2, varscan2
- HMCN1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746256161, COSV99637771; called by muse, mutect2, varscan2
- KIAA1549L | c.4226G>A p.R1409H (on ENST00000321505; = p.R1706H on NM_012194.3) | Missense Mutation (SNP) | VAF 189/487 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565978185, COSV58585296; called by muse, mutect2, varscan2
- KIF4B | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 156/351 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577708925; called by muse, mutect2, varscan2
- LGI3 | c.207-5C>T | Splice Region (SNP) | VAF 57/117 reads (49%) | catalogued as rs374572103; called by muse, mutect2, varscan2
- LYN | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV70205763; called by muse, mutect2, varscan2
- MAGEE1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV63910436; called by muse, varscan2
- NCOA2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1299587804, COSV71763631; called by muse, mutect2, varscan2
- NDN | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 198/296 reads (67%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as rs769908982, COSV100086198; called by muse, mutect2, varscan2
- NTAQ1 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as COSV99783629; called by muse, mutect2, varscan2
- OBSCN | c.13519G>A p.A4507T | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs571136484; called by muse, mutect2, varscan2
- POTEI | c.288C>A p.S96R | Missense Mutation (SNP) | VAF 132/530 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.316); catalogued as rs773696885; called by mutect2, varscan2
- PPP1R18 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs747076045, COSV51295175; called by muse, mutect2, varscan2
- PRSS21 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 160/442 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs186228582; called by muse, mutect2, varscan2
- RUNX1T1 | c.1538A>C p.E513A (on ENST00000265814 / NM_001198628.1; = p.E486A on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99750994; called by muse, mutect2, varscan2
- SCRIB | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372586260, COSV57590954; called by muse, mutect2, varscan2
- SEMG1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs770232552, COSV54872445; called by muse, mutect2, varscan2
- SLFN13 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1455856021; called by muse, mutect2, varscan2
- SUGP1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs150298383; called by muse, mutect2, varscan2
- SVOPL | c.605G>A p.R202H (on ENST00000419765; = p.R50H on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151301864, COSV99065539; called by muse, mutect2, varscan2
- THSD7A | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 79/146 reads (54%) | catalogued as rs777727562, COSV69855816; called by muse, mutect2, varscan2
- TIE1 | c.3289C>T p.R1097* | Nonsense Mutation (SNP) | VAF 159/401 reads (40%) | catalogued as rs1462518808; called by muse, mutect2, varscan2
- TRIB2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 73/398 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs762835253, COSV50224921; called by muse, mutect2, varscan2
- TRPV6 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs376154020; called by muse, mutect2, varscan2
- ZNF385C | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs782747386, COSV56918238; called by muse, mutect2, varscan2
- ZNF496 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54177855; called by muse, mutect2, varscan2
- ARID4B | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ASMT | c.471G>C p.M157I | Missense Mutation (SNP) | VAF 90/490 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CCDC120 | c.76dup p.Q26Pfs*12 | Frame Shift Ins (INS) | VAF 78/283 reads (28%) | called by mutect2, pindel, varscan2
- CDH12 | c.1717G>C p.D573H | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTBP1 | c.763-1G>A p.X255_splice | Splice Site (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- DAB2 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DPY19L1 | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DUSP14 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 131/332 reads (39%) | called by muse, mutect2, varscan2
- EDNRB | c.1170G>A p.M390I (on ENST00000377211 / NM_001201397.1; = p.M300I on NM_000115.5) | Missense Mutation (SNP) | VAF 85/309 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- EOMES | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERN2 | c.1759del p.H587Tfs*16 | Frame Shift Del (DEL) | VAF 82/221 reads (37%) | called by mutect2, pindel, varscan2
- FREM2 | c.4454T>A p.L1485Q | Missense Mutation (SNP) | VAF 83/638 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GJD2 | c.481A>C p.S161R | Missense Mutation (SNP) | VAF 265/453 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HUWE1 | c.1247T>C p.I416T | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- KATNIP | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTUS1 | c.3434C>T p.A1145V (on ENST00000262102 / NM_001363061.1; = p.A311V on NM_020749.4) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO16 | c.4388C>T p.A1463V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ODF2 | c.2065A>G p.K689E (on ENST00000434106 / NM_153433.2; = p.K665E on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ORMDL1 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 211/903 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PDE10A | c.1603C>G p.H535D | Missense Mutation (SNP) | VAF 94/262 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PDXDC1 | c.390-2_390-1insT p.X130_splice | Splice Site (INS) | VAF 36/125 reads (29%) | called by mutect2, pindel, varscan2
- PLEKHB2 | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM47 | c.546del p.I182Mfs*10 | Frame Shift Del (DEL) | VAF 80/353 reads (23%) | called by mutect2, pindel, varscan2
- ROBO2 | c.3208del p.A1070Pfs*103 | Frame Shift Del (DEL) | VAF 58/256 reads (23%) | called by pindel*, varscan2
- SCN7A | c.1909T>A p.F637I | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SEMA3D | c.2159T>G p.L720R | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SOBP | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2
- TBC1D25 | c.971C>A p.T324N | Missense Mutation (SNP) | VAF 109/343 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TCP11L2 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNPO3 | c.2504_2514del p.S835Tfs*17 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- TTN | c.28591C>T p.R9531* (on ENST00000591111; = p.R8604* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/150 reads (28%) | called by muse, mutect2, varscan2
- UNC13A | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- VIP | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- XPO7 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFC3H1 | c.173del p.P58Lfs*26 | Frame Shift Del (DEL) | VAF 119/312 reads (38%) | called by mutect2, pindel, varscan2
- ZIC3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 165/470 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRD1 | c.90G>A p.S30= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs748431281, COSV55442071; called by muse, mutect2
- APOL5 | c.36C>T p.P12= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs201209006; called by muse, mutect2, varscan2
- BAHCC1 | c.3654G>A p.R1218= | Silent (SNP) | VAF 84/203 reads (41%) | called by muse, mutect2, varscan2
- CASR | c.1212C>T p.V404= | Silent (SNP) | VAF 153/373 reads (41%) | catalogued as rs967661303, COSV56135617; called by muse, mutect2, varscan2
- DBX1 | c.633C>T p.R211= | Silent (SNP) | VAF 107/253 reads (42%) | catalogued as rs1450475834; called by muse, mutect2, varscan2
- DYRK1B | c.423C>A p.I141= | Silent (SNP) | VAF 64/157 reads (41%) | called by mutect2, varscan2
- FKBP6 | c.51C>T p.P17= | Silent (SNP) | VAF 195/354 reads (55%) | catalogued as rs1563308143; called by muse, mutect2, varscan2
- FNDC1 | c.2271G>A p.A757= | Silent (SNP) | VAF 134/380 reads (35%) | catalogued as rs758442513, COSV51947068; called by muse, mutect2, varscan2
- KIF4B | c.3378G>A p.K1126= | Silent (SNP) | VAF 138/394 reads (35%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3498G>A p.V1166= | Silent (SNP) | VAF 80/217 reads (37%) | called by muse, mutect2, varscan2
- PCDH9 | c.3591G>A p.Q1197= (on ENST00000377865 / NM_203487.3; = p.Q1163= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/512 reads (24%) | called by muse, mutect2, varscan2
- PCDHB12 | c.1836C>T p.P612= | Silent (SNP) | VAF 404/1010 reads (40%) | catalogued as COSV53396788; called by muse, mutect2, varscan2
- PCDHGA12 | c.1620G>A p.P540= | Silent (SNP) | VAF 148/457 reads (32%) | catalogued as COSV52747060; called by muse, mutect2, varscan2
- PCDHGA6 | c.276C>T p.R92= | Silent (SNP) | VAF 146/315 reads (46%) | catalogued as rs1179448303, COSV54021739; called by muse, varscan2
- PHLDB3 | c.1086C>T p.A362= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as rs780745027; called by muse, mutect2, varscan2
- PIGO | c.2091C>T p.P697= | Silent (SNP) | VAF 208/549 reads (38%) | catalogued as rs751948800; called by muse, mutect2, varscan2
- SEC16A | c.4923C>T p.G1641= | Silent (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- SEMA3D | c.2157C>T p.I719= | Silent (SNP) | VAF 61/287 reads (21%) | catalogued as rs780543746; called by muse, mutect2, varscan2
- SF3B2 | c.1029C>A p.S343= | Silent (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- SLC35G4 | c.150T>C p.P50= | Silent (SNP) | VAF 200/332 reads (60%) | called by muse, mutect2
- SOX11 | c.1062C>T p.S354= | Silent (SNP) | VAF 62/183 reads (34%) | called by muse, mutect2, varscan2
- SPOCK3 | c.948T>A p.P316= | Silent (SNP) | VAF 56/123 reads (46%) | called by muse, mutect2, varscan2
- TANGO6 | c.2076G>A p.T692= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as rs375595567; called by muse, mutect2, varscan2
- TENM3 | c.177C>T p.Y59= | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as rs758643488, COSV69302654; called by muse, mutect2, varscan2
- THSD7A | c.3168G>A p.K1056= | Silent (SNP) | VAF 50/174 reads (29%) | catalogued as rs1288031428; called by muse, mutect2, varscan2
- XPA | c.315C>T p.C105= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs138536873; ClinVar: likely benign; called by muse, mutect2, varscan2
- XPA | c.12C>T p.A4= | Silent (SNP) | VAF 137/313 reads (44%) | catalogued as rs377130468; called by muse, mutect2, varscan2
- XPO1 | c.87T>C p.D29= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- XYLB | c.267C>T p.V89= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs962420781, COSV52911656; called by muse, mutect2, varscan2
- AC011840.1 | n.894G>A | RNA (SNP) | VAF 198/516 reads (38%) | catalogued as rs1448004726; called by muse, mutect2, varscan2
- ARPP21 | c.795+418G>A | Intron (SNP) | VAF 88/270 reads (33%) | catalogued as rs1002280797; called by muse, mutect2, varscan2
- C1orf194 | c.*12C>T | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, varscan2
- CLDN15 | c.217+522C>T | Intron (SNP) | VAF 35/231 reads (15%) | called by muse, mutect2, varscan2
- CYP2B7P | n.552C>T | RNA (SNP) | VAF 91/252 reads (36%) | called by muse, mutect2, varscan2
- CYP7B1 | c.-91G>A | 5'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- ESRRG | c.*353C>T | 3'UTR (SNP) | VAF 8/27 reads (30%) | catalogued as rs920519408; called by muse, mutect2
- ETV2 | c.71-24A>G | Intron (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- LINC02692 | n.479C>T | RNA (SNP) | VAF 46/133 reads (35%) | catalogued as rs531066239; called by muse, mutect2, varscan2
- MIR7162 | chr10:30365020 G>A | 3'Flank (SNP) | VAF 96/237 reads (41%) | catalogued as rs751509969; called by muse, mutect2, varscan2
- NUB1 | c.1467+167G>A | Intron (SNP) | VAF 42/152 reads (28%) | catalogued as rs1284759437; called by muse, mutect2, varscan2
- PEG10 | c.*696C>T | 3'UTR (SNP) | VAF 81/557 reads (15%) | catalogued as COSV101509861; called by muse, mutect2, varscan2
- SEMA4C | c.110-214G>A | Intron (SNP) | VAF 68/171 reads (40%) | called by muse, mutect2, varscan2
- SPTLC2 | c.851-19T>C | Intron (SNP) | VAF 61/76 reads (80%) | called by muse, mutect2, varscan2
- ZNF10 | c.-23G>T | 5'UTR (SNP) | VAF 33/57 reads (58%) | catalogued as rs769528686; called by muse, varscan2
